Somatic mutation profile of tumor specimen BA2073D (aliquot aq-BA2073D) from BEATAML1.0 case 2042, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.1 years (26,352 days).
Specimen BA2073D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a96a343-bc6a-4ced-b7c1-11825e5a027f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2439D (Solid Tissue Normal), aliquot aq-BA2439D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8745950-a645-4f0a-8c15-a5bfe1176c74

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, Frame Shift Ins 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 34/96 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1900_1922del p.E635Rfs*15 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs766433101; called by mutect2, varscan2
- MTA2 | c.866A>T p.D289V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs377278798; called by muse, mutect2, varscan2
- OR52R1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as rs1326970300; called by muse, mutect2, varscan2
- SDK1 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs145189416; called by muse, varscan2
- ZNF729 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs759701802; called by muse, mutect2, varscan2
- FAT4 | c.11414A>C p.H3805P | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PGM2 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PLD4 | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCP2 | c.828dup p.G277Wfs*3 | Frame Shift Ins (INS) | VAF 26/64 reads (41%) | called by mutect2, varscan2
- USP9X | c.2555_2556insGCTTTGCCCG p.V853Lfs*14 | Frame Shift Ins (INS) | VAF 6/64 reads (9%) | called by mutect2, pindel
- BLK | c.117G>A p.P39= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs745995566, COSV52050250, COSV52052888; called by muse, mutect2, varscan2
- FAM83B | c.616C>A p.R206= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as COSV60919763; called by muse, mutect2
- LENG8 | c.1513C>A p.R505= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- C3orf84 | c.141+84C>T | Intron (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- DERA | c.750+79C>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
